Somatic mutation profile of tumor specimen TARGET-10-PARUCI-09A (aliquot TARGET-10-PARUCI-09A-01D) from TARGET case TARGET-10-PARUCI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,187 days).
Specimen TARGET-10-PARUCI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac4b4c7e-7c42-47df-8213-2b0899bba913.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARUCI-10A (Blood Derived Normal), aliquot TARGET-10-PARUCI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9d8bc5f-10fd-450f-af22-870a0fc8f958

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Intron 2, Frame Shift Del 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CLCN4 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs184264157, COSV66468523; called by muse, mutect2, varscan2
- EGR2 | c.1339G>A p.V447M | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as rs759547856, COSV54346263; called by muse, mutect2, varscan2
- FAM199X | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.947); catalogued as rs1009871599; called by muse, mutect2, varscan2
- GABRG2 | c.1430G>A p.R477H (on ENST00000361925 / NM_001375343.1; = p.R437H on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.997); catalogued as rs587780341, COSV62720285; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEMK1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs948127167; called by muse, mutect2, varscan2
- HMCN2 | c.14236C>T p.R4746W | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs774613996; called by muse, mutect2, varscan2
- ROS1 | c.5843G>A p.R1948H | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.061); catalogued as rs140237260; called by muse, mutect2, varscan2
- SIGLEC1 | c.3466C>T p.R1156W | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs768807544; called by muse, mutect2, varscan2
- RABGAP1L | c.735_736del p.Y245* | Frame Shift Del (DEL) | VAF 62/147 reads (42%) | called by mutect2, pindel, varscan2
- ZNF84 | c.1001T>A p.L334H | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDH10 | c.2286C>T p.Y762= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as rs775096429, COSV52580162; called by muse, mutect2, varscan2
- CFTR | c.3483C>T p.S1161= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as CM011285; called by muse, mutect2, varscan2
- MINDY4 | c.2253C>T p.N751= | Silent (SNP) | VAF 52/115 reads (45%) | catalogued as rs375287585; called by muse, mutect2, varscan2
- ZNF600 | c.1188G>A p.A396= | Silent (SNP) | VAF 83/196 reads (42%) | catalogued as rs764707988; called by muse, mutect2, varscan2
- CD300LG | c.885+772G>T | Intron (SNP) | VAF 9/19 reads (47%) | catalogued as COSV99517652; called by muse, mutect2
- GPBP1L1 | c.1045-82G>A | Intron (SNP) | VAF 21/45 reads (47%) | catalogued as rs1313663729; called by muse, mutect2, varscan2
- GPR42 | c.*53C>T | 3'UTR (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- KLK14 | c.-89G>A | 5'UTR (SNP) | VAF 6/15 reads (40%) | catalogued as rs773435362, COSV99335820; called by muse, mutect2, varscan2
